Somatic mutation profile of tumor specimen 15524912-685a-47ce-a824-567848 (aliquot 15524912-685a-47ce-a824-567848_D6) from CPTAC case 04OV049, project CPTAC-2 (Other and unspecified female genital organs — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Fallopian tube; FIGO stage: Stage IIIC.
Specimen 15524912-685a-47ce-a824-567848: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e0b0e8a2-c19e-4cd8-be1e-37eb8ef750c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 68cd7f58-ee24-490b-b3d1-ddad43 (Blood Derived Normal), aliquot 68cd7f58-ee24-490b-b3d1-ddad43_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a16c2791-eec1-469a-99bf-b5323a6d1aff

The open-access MAF lists 196 somatic variants for this specimen: 132 protein-altering or splice-affecting, 43 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 115, Silent 43, Intron 12, Nonsense Mutation 6, Splice Site 5, Frame Shift Del 4, RNA 3, 3'UTR 2, 5'Flank 2, 5'UTR 1, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.578A>T p.H193L | Missense Mutation (SNP) | VAF 166/429 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ACSM6 | c.451C>A p.R151S | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.078); catalogued as COSV58978473, COSV58979152; called by muse, mutect2, varscan2
- AKAP9 | c.1585C>G p.Q529E | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as rs780547389, COSV62348192; called by muse, mutect2, varscan2
- AL592490.1 | c.2008C>T p.R670* | Nonsense Mutation (SNP) | VAF 34/308 reads (11%) | catalogued as rs1313291049, COSV69426707; called by muse, mutect2, varscan2
- ANKRD1 | c.595C>A p.L199M | Missense Mutation (SNP) | VAF 93/468 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.524); catalogued as rs1395562720; called by muse, mutect2, varscan2
- APPBP2 | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.857); catalogued as COSV99319491; called by muse, mutect2, varscan2
- CASQ1 | c.208C>G p.L70V | Missense Mutation (SNP) | VAF 118/519 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.412); catalogued as rs1356210195; called by muse, mutect2, varscan2
- CBR3 | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 22/264 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as rs901640160; called by muse, mutect2
- CCDC80 | c.611C>T p.T204I | Missense Mutation (SNP) | VAF 66/730 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs759154848; called by muse, mutect2
- CELF3 | c.967G>C p.A323P | Missense Mutation (SNP) | VAF 10/245 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.737); catalogued as COSV99310455; called by muse, mutect2
- COL15A1 | c.4049C>T p.T1350M | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.287); catalogued as rs374842979; called by muse, mutect2, varscan2
- DHH | c.110G>C p.R37P | Missense Mutation (SNP) | VAF 89/229 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.013); catalogued as rs138814945; called by muse, mutect2, varscan2
- DKK2 | c.496G>T p.G166* | Nonsense Mutation (SNP) | VAF 18/57 reads (32%) | catalogued as COSV53403665; called by muse, mutect2, varscan2
- DOCK11 | c.1112G>C p.C371S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99353207; called by muse, mutect2
- ESYT3 | c.2535T>G p.S845R | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.764); catalogued as COSV67440389; called by muse, mutect2, varscan2
- FAM90A26 | c.1091C>T p.P364L | Missense Mutation (SNP) | VAF 170/422 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs1446085686; called by muse, mutect2, varscan2
- GABRG1 | c.1238C>A p.A413D | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.04); catalogued as COSV54962822; called by muse, mutect2, varscan2
- GPR31 | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 60/409 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.12); catalogued as rs770088662; called by muse, mutect2, varscan2
- GPR55 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 24/234 reads (10%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as rs766293332, COSV101235720; called by muse, mutect2, varscan2
- JCAD | c.2242C>G p.R748G | Missense Mutation (SNP) | VAF 35/342 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.097); catalogued as rs758587099, COSV100948370; called by muse, mutect2, varscan2
- JHY | c.196G>T p.G66C | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as COSV56222155; called by muse, mutect2, varscan2
- KRT85 | c.516C>G p.F172L | Missense Mutation (SNP) | VAF 87/648 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.174); catalogued as COSV57736503; called by muse, mutect2, varscan2
- LHX5 | c.919C>G p.P307A | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.437); catalogued as rs1016759370, COSV55663305; called by muse, mutect2
- LPIN3 | c.1877G>A p.R626H | Missense Mutation (SNP) | VAF 38/432 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs775885873; called by muse, mutect2
- MAML3 | c.787G>C p.E263Q | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.796); catalogued as COSV100505386; called by muse, mutect2, varscan2
- MYLK2 | c.67G>A p.G23S | Missense Mutation (SNP) | VAF 63/394 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as rs1157509610; called by muse, mutect2, varscan2
- MYT1 | c.529G>C p.E177Q | Missense Mutation (SNP) | VAF 37/328 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.502); catalogued as COSV60513987; called by muse, mutect2, varscan2
- NECAB2 | c.202-2A>C p.X68_splice | Splice Site (SNP) | VAF 20/141 reads (14%) | catalogued as rs1454677125; called by muse, mutect2, varscan2
- OR4A15 | c.701C>A p.A234D | Missense Mutation (SNP) | VAF 20/187 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs199544134, COSV59035778, COSV59037883; called by muse, mutect2, varscan2
- OXR1 | c.611C>T p.S204F (on ENST00000442977 / NM_001198532.1; = p.S203F on NM_018002.3) | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56333352; called by muse, mutect2, varscan2
- PLCD3 | c.430A>C p.K144Q | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.098); catalogued as rs1189365456; called by muse, mutect2
- RNASE10 | c.427G>C p.E143Q | Missense Mutation (SNP) | VAF 30/214 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100116149; called by muse, mutect2, varscan2
- RPLP0 | c.839C>T p.P280L | Missense Mutation (SNP) | VAF 45/145 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.537); catalogued as rs1216677411; called by muse, mutect2, varscan2
- SLC13A4 | c.1211T>C p.F404S | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV100818914; called by muse, mutect2
- SLC5A6 | c.736C>G p.L246V | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.374); catalogued as COSV60160095; called by muse, mutect2, varscan2
- SLC6A2 | c.763G>C p.G255R | Missense Mutation (SNP) | VAF 127/614 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54913743, COSV54925473; called by muse, mutect2, varscan2
- SLCO4A1 | c.1715C>G p.S572* | Nonsense Mutation (SNP) | VAF 48/788 reads (6%) | catalogued as COSV53890360; called by muse, mutect2
- SRF | c.1000G>A p.G334R | Missense Mutation (SNP) | VAF 72/332 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as rs1239957151; called by muse, mutect2, varscan2
- SYNPO2 | c.1781G>T p.G594V | Missense Mutation (SNP) | VAF 75/301 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61108061; called by muse, mutect2, varscan2
- TACC2 | c.8551A>C p.K2851Q (on ENST00000334433; = p.K929Q on NM_006997.4) | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755599004; called by muse, mutect2, varscan2
- TEX35 | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 147/263 reads (56%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.511); catalogued as rs758053108, COSV104383283; called by muse, mutect2, varscan2
- TLN1 | c.4777C>T p.R1593W | Missense Mutation (SNP) | VAF 44/189 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as rs267602229, COSV59206053; called by muse, mutect2, varscan2
- TMC7 | c.1279A>G p.K427E | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.025); catalogued as rs1160583917; called by muse, mutect2, varscan2
- TNC | c.6026C>T p.A2009V | Missense Mutation (SNP) | VAF 30/188 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.364); catalogued as rs200465690, COSV100406029; called by muse, mutect2, varscan2
- TOP1 | c.1810G>C p.E604Q | Missense Mutation (SNP) | VAF 22/179 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.071); catalogued as COSV63694237; called by muse, mutect2, varscan2
- TRIL | c.309C>G p.F103L | Missense Mutation (SNP) | VAF 42/323 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV59866976; called by muse, mutect2, varscan2
- TTBK1 | c.1417G>C p.E473Q | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.777); catalogued as COSV52490502; called by muse, mutect2
- VARS1 | c.3071A>T p.D1024V | Missense Mutation (SNP) | VAF 20/302 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1416810943; called by muse, mutect2
- VWF | c.4439C>T p.P1480L | Missense Mutation (SNP) | VAF 54/722 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.244); catalogued as rs778742589, COSV54632336; called by muse, mutect2
- ZBTB12 | c.41G>A p.G14D | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1306084305; called by muse, mutect2
- ZDHHC15 | c.449+1G>A p.X150_splice | Splice Site (SNP) | VAF 13/44 reads (30%) | catalogued as rs1454727400; called by muse, mutect2, varscan2
- ZNF107 | c.43G>C p.D15H | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.127); catalogued as COSV61328383, COSV61329013; called by muse, mutect2, varscan2
- AC098582.1 | c.1678G>T p.V560L | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- ACVR2B | c.651G>T p.K217N | Missense Mutation (SNP) | VAF 89/710 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS19 | c.1460del p.A487Vfs*72 | Frame Shift Del (DEL) | VAF 7/36 reads (19%) | called by mutect2, pindel, varscan2
- ADGRG4 | c.4553T>A p.V1518D | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- B4GALT5 | c.1004T>G p.V335G | Missense Mutation (SNP) | VAF 46/236 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- BFSP1 | c.1540C>G p.P514A | Missense Mutation (SNP) | VAF 43/503 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- CALD1 | c.2331C>A p.N777K (on ENST00000361675 / NM_033138.4; = p.N522K on NM_004342.7) | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CAMTA2 | c.2506C>G p.L836V | Missense Mutation (SNP) | VAF 43/230 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- CBL | c.1331G>A p.R444K | Missense Mutation (SNP) | VAF 42/333 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.031); called by muse, varscan2
- CCDC169 | c.85G>C p.D29H | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- CEP250 | c.4467A>T p.L1489F | Missense Mutation (SNP) | VAF 17/269 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2
- CNOT2 | c.756G>C p.L252F | Missense Mutation (SNP) | VAF 61/138 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- CNPY3 | c.587A>G p.N196S | Missense Mutation (SNP) | VAF 35/179 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- COL4A3 | c.3418G>C p.G1140R | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CORO2A | c.1121G>A p.G374E | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- CR1 | c.4649C>A p.T1550N | Missense Mutation (SNP) | VAF 36/382 reads (9%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.809); called by muse, mutect2
- CRYBG2 | c.2726T>G p.L909R | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CYHR1 | c.974A>T p.E325V | Missense Mutation (SNP) | VAF 53/974 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.446); called by muse, mutect2
- DDX24 | c.565G>C p.A189P | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- DDX50 | c.431T>C p.I144T | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- DYNC2H1 | c.9440+1G>T p.X3147_splice | Splice Site (SNP) | VAF 6/45 reads (13%) | called by muse, mutect2, varscan2
- FAM153A | c.857A>C p.K286T | Missense Mutation (SNP) | VAF 38/491 reads (8%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.607); called by muse, mutect2
- FNDC1 | c.2444G>A p.G815E | Missense Mutation (SNP) | VAF 234/444 reads (53%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- GABRR3 | c.1183G>C p.D395H | Missense Mutation (SNP) | VAF 20/281 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.895); called by muse, mutect2
- GAS8 | c.502_517delinsCAG p.T168Qfs*22 | Frame Shift Del (DEL) | VAF 32/132 reads (24%) | called by pindel, varscan2*
- GOLGB1 | c.4726C>G p.L1576V | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- GON4L | c.4569G>C p.E1523D | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- GPATCH1 | c.1771G>A p.V591I | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- H2AC6 | c.347T>A p.L116H | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.254); called by muse, mutect2
- HEATR6 | c.2173G>T p.D725Y | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- HELB | c.1113G>A p.M371I | Missense Mutation (SNP) | VAF 29/194 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- HOGA1 | c.899_924del p.G300Afs*5 | Frame Shift Del (DEL) | VAF 50/260 reads (19%) | called by mutect2, pindel, varscan2
- HOXA11 | c.706T>C p.S236P | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.013); called by muse, mutect2
- IFNGR2 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 42/380 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- ING1 | c.17G>C p.C6S | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ITGB4 | c.109A>G p.S37G | Missense Mutation (SNP) | VAF 10/302 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); called by muse, mutect2
- ITM2B | c.164G>C p.W55S | Missense Mutation (SNP) | VAF 32/206 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- KIF15 | c.3312G>T p.Q1104H | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.121); called by muse, mutect2
- KIF15 | c.3313C>T p.H1105Y | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.024); called by muse, mutect2
- LAMC2 | c.3280A>T p.T1094S | Missense Mutation (SNP) | VAF 64/312 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- LIPF | c.896A>T p.K299M | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- MIER2 | c.626A>T p.N209I | Missense Mutation (SNP) | VAF 62/172 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MPHOSPH9 | c.2534C>A p.P845H | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MROH1 | c.2254C>T p.P752S | Missense Mutation (SNP) | VAF 30/940 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MTMR12 | c.700A>C p.K234Q | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MYH15 | c.392T>G p.M131R | Missense Mutation (SNP) | VAF 23/210 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYH15 | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.127); called by muse, varscan2
- NDUFAF8 | c.85G>T p.A29S | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- NEUROD6 | c.4T>A p.L2I | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, varscan2
- OR2A5 | c.708G>T p.K236N | Missense Mutation (SNP) | VAF 163/650 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OTUD7A | c.791_811del p.V264_W270del (on ENST00000307050 / NM_001382637.1; = p.X261_splice on NM_130901.3) | In Frame Del (DEL) | VAF 28/114 reads (25%) | called by pindel, varscan2
- PAFAH2 | c.408C>T p.H136= | Splice Region (SNP) | VAF 11/55 reads (20%) | called by muse, mutect2, varscan2
- PIP4P2 | c.266del p.N89Tfs*26 | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- PLEKHG6 | c.1438T>A p.F480I | Missense Mutation (SNP) | VAF 106/564 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- PPFIA3 | c.2542G>C p.E848Q | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.034); called by muse, mutect2
- PPP4R2 | c.470G>A p.G157E | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2
- RANBP9 | c.1565C>T p.A522V | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RASAL2 | c.1106G>C p.R369T | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBPJL | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 52/357 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- RIN2 | c.2777A>G p.K926R (on ENST00000255006 / NM_001242581.1; = p.K877R on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- SHROOM1 | c.64C>G p.L22V | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- SLC17A1 | c.410T>C p.V137A | Missense Mutation (SNP) | VAF 78/283 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SLC17A3 | c.62A>C p.Q21P | Missense Mutation (SNP) | VAF 11/179 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.009); called by muse, mutect2
- SLC4A9 | c.2424C>G p.I808M (on ENST00000507527 / NM_001258428.2; = p.I784M on NM_031467.3) | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC5A7 | c.178+1G>A p.X60_splice | Splice Site (SNP) | VAF 19/68 reads (28%) | called by muse, mutect2
- SLC7A9 | c.272C>A p.T91N | Missense Mutation (SNP) | VAF 98/408 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SLCO1B1 | c.1405C>T p.Q469* | Nonsense Mutation (SNP) | VAF 7/138 reads (5%) | called by muse, mutect2
- TCEA2 | c.486C>G p.D162E | Missense Mutation (SNP) | VAF 15/257 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.392); called by muse, mutect2
- THAP7 | c.82C>A p.L28I | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- TMOD2 | c.872A>G p.N291S | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- TPTE | c.1214A>T p.N405I (on ENST00000618007 / NM_199261.4; = p.N387I on NM_199259.4) | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2
- TRIM42 | c.862A>C p.K288Q | Missense Mutation (SNP) | VAF 73/615 reads (12%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- TTC28 | c.5662C>T p.Q1888* | Nonsense Mutation (SNP) | VAF 25/102 reads (25%) | called by muse, mutect2, varscan2
- TTN | c.56555C>T p.T18852I (on ENST00000591111; = p.T11428I on NM_003319.4) | Missense Mutation (SNP) | VAF 24/168 reads (14%) | PolyPhen benign (0.116); called by muse, mutect2, varscan2
- UQCRC1 | c.258T>A p.N86K | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.409); called by muse, mutect2, varscan2
- UTRN | c.6058-1G>A p.X2020_splice | Splice Site (SNP) | VAF 7/27 reads (26%) | called by muse, mutect2
- ZNF106 | c.1732A>T p.K578* | Nonsense Mutation (SNP) | VAF 33/140 reads (24%) | called by muse, mutect2, varscan2
- ZNF335 | c.1163A>T p.D388V | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.093); called by muse, mutect2
- ZNF420 | c.1742A>C p.H581P | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF662 | c.1181G>A p.G394E | Missense Mutation (SNP) | VAF 22/228 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); called by muse, mutect2
- ABCA12 | c.570A>G p.G190= | Silent (SNP) | VAF 87/166 reads (52%) | called by muse, mutect2, varscan2
- ADGRF5 | c.3951T>C p.F1317= | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as rs1462173290; called by muse, mutect2
- APBA2 | c.267C>G p.G89= | Silent (SNP) | VAF 200/822 reads (24%) | catalogued as COSV68790497, COSV68794093; called by muse, mutect2, varscan2
- ATAD2B | c.2556G>T p.L852= | Silent (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2
- B4GALT5 | c.1005C>T p.V335= | Silent (SNP) | VAF 46/232 reads (20%) | called by muse, mutect2, varscan2
- C2orf78 | c.441G>A p.V147= | Silent (SNP) | VAF 162/423 reads (38%) | called by muse, mutect2, varscan2
- CACNA1S | c.708G>A p.T236= | Silent (SNP) | VAF 142/461 reads (31%) | catalogued as rs754213830, COSV62943187; called by muse, varscan2
- CDHR4 | c.468C>A p.L156= | Silent (SNP) | VAF 37/366 reads (10%) | called by muse, mutect2, varscan2
- COL2A1 | c.2496A>G p.P832= | Silent (SNP) | VAF 22/143 reads (15%) | called by muse, mutect2, varscan2
- CYP2D7 | c.726C>T p.R242= | Silent (SNP) | VAF 90/584 reads (15%) | catalogued as COSV100809460; called by muse, mutect2
- DDC | c.1113C>G p.V371= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as COSV63567468; called by muse, mutect2, varscan2
- DYNC1H1 | c.6660G>C p.L2220= | Silent (SNP) | VAF 87/273 reads (32%) | called by muse, mutect2, varscan2
- FAM111B | c.42T>G p.A14= | Silent (SNP) | VAF 7/66 reads (11%) | called by muse, mutect2, varscan2
- FBXO42 | c.1404A>T p.P468= | Silent (SNP) | VAF 33/250 reads (13%) | called by muse, mutect2, varscan2
- FGFBP2 | c.15C>T p.P5= | Silent (SNP) | VAF 17/96 reads (18%) | called by muse, mutect2, varscan2
- GCN1 | c.1089C>G p.L363= | Silent (SNP) | VAF 6/23 reads (26%) | called by muse, mutect2, varscan2
- GFI1 | c.207C>G p.S69= | Silent (SNP) | VAF 22/147 reads (15%) | called by muse, mutect2, varscan2
- GLUD1 | c.666T>G p.P222= | Silent (SNP) | VAF 16/196 reads (8%) | called by muse, mutect2
- GOLGA6L10 | c.1401C>A p.V467= | Silent (SNP) | VAF 56/1920 reads (3%) | called by muse, mutect2
- HSPA13 | c.1107C>A p.L369= | Silent (SNP) | VAF 30/322 reads (9%) | catalogued as COSV53466608; called by muse, mutect2
- KIF7 | c.18G>A p.Q6= | Silent (SNP) | VAF 19/235 reads (8%) | called by muse, mutect2
- KRTAP19-1 | c.12C>T p.Y4= | Silent (SNP) | VAF 53/182 reads (29%) | catalogued as rs200649377, COSV66861170; called by muse, mutect2, varscan2
- L1CAM | c.624C>A p.I208= | Silent (SNP) | VAF 95/836 reads (11%) | called by muse, mutect2, varscan2
- MBD3 | c.504G>A p.V168= | Silent (SNP) | VAF 43/220 reads (20%) | catalogued as rs1168900036; called by muse, mutect2, varscan2
- MED16 | c.1803G>A p.T601= | Silent (SNP) | VAF 24/119 reads (20%) | catalogued as rs142768500; called by muse, mutect2, varscan2
- MYMK | c.162C>A p.G54= | Silent (SNP) | VAF 41/144 reads (28%) | called by muse, mutect2, varscan2
- MYO9A | c.3549T>C p.S1183= | Silent (SNP) | VAF 13/152 reads (9%) | called by muse, mutect2
- NALCN | c.855C>A p.L285= | Silent (SNP) | VAF 9/87 reads (10%) | called by muse, mutect2, varscan2
- PDE3A | c.411C>T p.F137= | Silent (SNP) | VAF 26/429 reads (6%) | catalogued as rs1019689936; called by muse, mutect2
- PDS5A | c.2880T>A p.P960= | Silent (SNP) | VAF 11/154 reads (7%) | called by muse, mutect2
- POFUT1 | c.675G>A p.Q225= | Silent (SNP) | VAF 22/316 reads (7%) | called by muse, mutect2
- PPP2R1A | c.567G>C p.L189= | Silent (SNP) | VAF 42/203 reads (21%) | catalogued as rs140667985; called by muse, mutect2, varscan2
- RIF1 | c.1335G>A p.L445= | Silent (SNP) | VAF 9/64 reads (14%) | called by muse, mutect2, varscan2
- SEPTIN4 | c.162C>A p.T54= | Silent (SNP) | VAF 15/81 reads (19%) | called by muse, mutect2, varscan2
- SESN2 | c.1365G>A p.V455= | Silent (SNP) | VAF 19/131 reads (15%) | catalogued as rs1156308799; called by muse, mutect2, varscan2
- SIN3A | c.3798C>T p.Y1266= | Silent (SNP) | VAF 45/222 reads (20%) | catalogued as rs768298196, COSV99145675; called by muse, mutect2, varscan2
- SLC22A23 | c.1929G>A p.P643= | Silent (SNP) | VAF 23/215 reads (11%) | catalogued as rs777092248, COSV66678489; called by muse, mutect2, varscan2
- SPTBN5 | c.5574G>A p.T1858= | Silent (SNP) | VAF 51/212 reads (24%) | catalogued as rs899364712; called by muse, mutect2, varscan2
- TBC1D21 | c.753C>T p.F251= | Silent (SNP) | VAF 35/280 reads (13%) | catalogued as rs750952235; called by muse, mutect2, varscan2
- TLE3 | c.342C>A p.V114= | Silent (SNP) | VAF 49/212 reads (23%) | called by muse, mutect2, varscan2
- UNC93B1 | c.810C>G p.G270= | Silent (SNP) | VAF 26/275 reads (9%) | catalogued as COSV57098548; called by muse, mutect2, varscan2
- USP7 | c.1650C>A p.I550= | Silent (SNP) | VAF 47/179 reads (26%) | called by muse, mutect2, varscan2
- ZNF585A | c.510G>A p.K170= (on ENST00000292841 / NM_001288800.2; = p.K115= on NM_152655.3) | Silent (SNP) | VAF 18/67 reads (27%) | called by muse, mutect2, varscan2
- ACTG1P17 | n.666_694del | RNA (DEL) | VAF 45/504 reads (9%) | called by mutect2, pindel
- AL121758.1 | c.*665A>G | 3'UTR (SNP) | VAF 99/243 reads (41%) | catalogued as rs1450804834; called by muse, mutect2, varscan2
- ATP1A3 | c.510+19G>A | Intron (SNP) | VAF 70/552 reads (13%) | catalogued as rs1555865337; called by muse, mutect2, varscan2
- DCHS2 | n.5482C>T | RNA (SNP) | VAF 7/70 reads (10%) | called by muse, mutect2, varscan2
- DHRS2 | c.421-1430G>A | Intron (SNP) | VAF 37/292 reads (13%) | called by muse, mutect2, varscan2
- HERC4 | c.1070-2553C>G | Intron (SNP) | VAF 12/72 reads (17%) | called by muse, mutect2, varscan2
- MARCHF1 | c.242+363T>A | Intron (SNP) | VAF 10/84 reads (12%) | called by muse, mutect2, varscan2
- MICA | c.*73G>T | 3'UTR (SNP) | VAF 9/109 reads (8%) | catalogued as COSV69826648; called by muse, mutect2
- MMP11 | c.1076-405A>T | Intron (SNP) | VAF 28/185 reads (15%) | called by muse, mutect2, varscan2
- NDUFV1 | c.327-11G>C | Intron (SNP) | VAF 47/325 reads (14%) | called by muse, mutect2, varscan2
- NOC2LP2 | n.933C>G | RNA (SNP) | VAF 166/607 reads (27%) | called by muse, mutect2, varscan2
- NR5A2 | c.1110+8808G>T | Intron (SNP) | VAF 18/53 reads (34%) | called by muse, mutect2, varscan2
- PIGQ | c.1531+256G>C | Intron (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2
- PIP5K1C | c.1920+949C>A | Intron (SNP) | VAF 60/144 reads (42%) | called by muse, mutect2, varscan2
- PRDM11 | chr11:45228049 G>C | 3'Flank (SNP) | VAF 55/218 reads (25%) | catalogued as rs1225790267; called by muse, mutect2, varscan2
- PRMT7 | chr16:68311053 G>A | 5'Flank (SNP) | VAF 22/142 reads (15%) | catalogued as rs898968482; called by muse, mutect2, varscan2
- PXK | c.102+474C>T | Intron (SNP) | VAF 15/133 reads (11%) | catalogued as rs1366597955; called by muse, mutect2, varscan2
- UBE4B | c.-17C>G | 5'UTR (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2, varscan2
- USP27X | chrX:49878626 G>C | 5'Flank (SNP) | VAF 56/512 reads (11%) | called by muse, mutect2, varscan2
- YPEL2 | c.117+127C>G | Intron (SNP) | VAF 15/142 reads (11%) | called by muse, mutect2, varscan2
- ZNF451 | c.186+2590A>G | Intron (SNP) | VAF 73/290 reads (25%) | called by muse, mutect2, varscan2
